FM case AD7638 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/2f3b0871-8878-46df-9340-d33c6ca72220

Male, 35.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
